Somatic mutation profile of tumor specimen TCGA-L5-A8NQ-01A (aliquot TCGA-L5-A8NQ-01A-11D-A36J-09) from TCGA case TCGA-L5-A8NQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 71.9 years (26,250 days).
Specimen TCGA-L5-A8NQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13307757-364c-493e-aa07-80a8428be55d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NQ-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NQ-11A-11D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbf3f7ec-7719-41a3-9881-b0b4453d51d2

The open-access MAF lists 224 somatic variants for this specimen: 164 protein-altering or splice-affecting, 52 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 52, Nonsense Mutation 11, Splice Site 5, Intron 3, 5'UTR 2, Translation Start Site 2, Frame Shift Ins 2, 3'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.1572+1G>A p.X524_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as rs1057520717, CS075105; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARFGEF2 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV100904275; called by muse, mutect2, varscan2
- ATP10A | c.3415G>A p.G1139R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63516863; called by muse, mutect2
- ATP1A2 | c.1273C>T p.L425F | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1446454612; called by muse, mutect2
- ATP6V1B1 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs202215158; called by muse, mutect2
- BCOR | c.4685C>G p.S1562* (on ENST00000378444 / NM_001123385.2; = p.S1528* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV60714590; called by muse, mutect2, varscan2
- BLM | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as COSV100757213; called by muse, mutect2
- C6orf118 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs750287336; called by muse, mutect2, varscan2
- CCDC93 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV60119832; called by muse, mutect2, varscan2
- CNTN1 | c.2966A>G p.Q989R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1489927231; called by muse, mutect2, varscan2
- COG4 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as COSV60424442; called by mutect2, varscan2
- CPNE1 | c.667C>G p.L223V (on ENST00000352393; = p.L228V on NM_003915.5) | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100467961; called by muse, mutect2
- DSG3 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs771167915, COSV57128203; called by muse, mutect2
- FBN1 | c.7183G>A p.G2395R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448650040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOCAD | c.4834G>A p.E1612K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.204); catalogued as rs1181547650; called by muse, mutect2, varscan2
- FOXR2 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100189545; called by muse, mutect2, varscan2
- GLG1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290562843; called by muse, mutect2, varscan2
- GRAMD4 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs751034556; called by muse, mutect2, varscan2
- HCFC1 | c.2795C>T p.S932L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.715); catalogued as COSV60069521; called by muse, mutect2, varscan2
- HIPK2 | c.159G>C p.Q53H | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV100702673; called by muse, mutect2
- IFT88 | c.2452G>A p.E818K (on ENST00000319980 / NM_001318493.2; = p.E809K on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs1348482594, COSV60675910; called by muse, mutect2, varscan2
- KANSL1 | c.3097C>T p.P1033S (on ENST00000574590 / NM_001193465.2; = p.P1034S on NM_015443.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52237170; called by muse, mutect2, varscan2
- KIAA1522 | c.2540C>T p.S847L (on ENST00000373480 / NM_001198972.2; = p.S906L on NM_020888.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs776125780, COSV53864939; called by muse, mutect2, varscan2
- LAMB1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.117); catalogued as COSV55962291; called by muse, mutect2, varscan2
- LIMK1 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs782450849; called by muse, mutect2
- LINGO1 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796527, COSV62436071; called by muse, mutect2
- LOXL3 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.063); catalogued as rs751944822; called by muse, mutect2, varscan2
- LRRC4C | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV53417184, COSV53429186; called by muse, mutect2, varscan2
- MACF1 | c.17663C>G p.S5888C (on ENST00000372915; = p.S3930C on NM_012090.5) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV57148079; called by muse, mutect2, varscan2
- MEGF8 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs750660042, COSV52090227; called by muse, mutect2
- MMP26 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.76); catalogued as rs773132017, COSV56172040; called by mutect2, varscan2
- MPO | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51858540; called by muse, mutect2, varscan2
- MYO16 | c.132C>A p.F44L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV51787839; called by muse, mutect2, varscan2
- MYOF | c.5188C>T p.H1730Y | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs777800718; called by muse, mutect2, varscan2
- NCOR1 | c.2927A>C p.Q976P | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as rs906979002; called by muse, mutect2, varscan2
- NELFE | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as rs775691868, COSV64810105; called by muse, mutect2, varscan2
- NPTX1 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60774862, COSV60775138; called by muse, mutect2
- NUP210L | c.4423C>A p.P1475T | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55150941; called by muse, mutect2
- PAM | c.2395C>G p.H799D | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs1377207526; called by muse, mutect2
- PCDHGA3 | c.1976C>T p.T659M | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as rs747365510; called by muse, mutect2, varscan2
- PDPR | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs368906299; called by muse, mutect2
- PERP | c.452G>A p.W151* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV101408570; called by muse, mutect2, varscan2
- PID1 | c.334G>A p.E112K (on ENST00000354069 / NM_001330156.1; = p.E110K on NM_017933.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs867123602, COSV100819535; called by muse, mutect2, varscan2
- PLOD3 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs764596991; called by muse, mutect2, varscan2
- PPIB | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757275030, COSV55519980, COSV55521585; called by muse, mutect2, varscan2
- PPP1R16B | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV55381725; called by muse, mutect2, varscan2
- RBP4 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139534453; called by muse, mutect2, varscan2
- REV3L | c.3379C>T p.R1127C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757261538; called by muse, mutect2, varscan2
- RFX6 | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV60585449; called by muse, mutect2, varscan2
- RPS6KL1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV63581928; called by muse, mutect2, varscan2
- SAP130 | c.988A>T p.I330F | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as COSV52094728; called by muse, mutect2
- SHOC1 | c.671-1G>A p.X224_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV59506762; called by muse, mutect2, varscan2
- SMR3A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/112 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV56951266; called by muse, mutect2
- SMTN | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60778317; called by muse, mutect2, varscan2
- SPATA9 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV57224205; called by muse, mutect2
- TBXT | c.668+1G>A p.X223_splice | Splice Site (SNP) | VAF 7/104 reads (7%) | catalogued as COSV99752483; called by muse, mutect2
- TDRD6 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759445214; called by muse, mutect2, varscan2
- TEP1 | c.1814G>A p.R605H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs201323276; called by mutect2, varscan2
- TRERF1 | c.2357G>C p.R786T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61678145; called by muse, mutect2, varscan2
- TSKS | c.400-1G>C p.X134_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | catalogued as COSV55876422; called by muse, mutect2, varscan2
- USP39 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1485348665, COSV60382746; called by muse, mutect2
- YWHAQ | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); catalogued as rs1173245074; called by muse, mutect2, varscan2
- ZEB2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs727504227; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZIM3 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.81); PolyPhen benign (0.161); catalogued as COSV99518901; called by muse, mutect2
- ZNF292 | c.6626C>T p.A2209V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV60535437; called by muse, mutect2, varscan2
- ZNF436 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100011404; called by muse, mutect2, varscan2
- ACE2 | c.2075C>T p.S692F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ADGRE2 | c.1913G>C p.S638T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.506); called by muse, mutect2
- ARHGEF1 | c.2095G>C p.D699H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- ASXL1 | c.3877G>A p.D1293N | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATR | c.5362G>T p.E1788* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- BBS4 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2
- BRD4 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BRPF3 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMKV | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CAPRIN2 | c.1652A>T p.N551I | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CFAP54 | c.5024C>G p.S1675C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFH | c.3395C>T p.S1132L | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2
- CNBD2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- COL21A1 | c.2473_2479dup p.P827Rfs*119 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | called by mutect2, varscan2
- COPB1 | c.2212G>C p.D738H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE2 | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2
- CSE1L | c.2473dup p.I825Nfs*5 | Frame Shift Ins (INS) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.2233G>C p.E745Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.232); called by muse, mutect2
- DGKD | c.1338G>A p.W446* (on ENST00000264057 / NM_152879.3; = p.W402* on NM_003648.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- DHX32 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2
- EFHC2 | c.988C>A p.Q330K | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- FAM107B | c.225G>C p.K75N (on ENST00000378458 / NM_001320737.1; = p.K250N on NM_031453.3) | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- FCHSD2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2
- FDPS | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by mutect2, varscan2
- FGD2 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); called by muse, mutect2
- FMN2 | c.4193C>A p.T1398N | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2
- HERC2 | c.10009C>T p.P3337S | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- HLTF | c.2212G>C p.E738Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HUNK | c.1089C>G p.I363M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by mutect2, varscan2
- IKBKB | c.2243A>T p.E748V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- IL10RB | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- IL16 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- IL16 | c.3388G>A p.G1130R (on ENST00000302987 / NM_172217.5; = p.G429R on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAM | c.3263C>T p.A1088V (on ENST00000648685 / NM_001145808.2; = p.A1087V on NM_000632.4) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KCTD18 | c.473G>C p.R158T | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.738); called by muse, mutect2
- KCTD7 | c.584C>T p.T195I (on ENST00000275532; = p.N208= on NM_153033.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- KDM4A | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF17 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KIF5B | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLB | c.2840C>G p.S947C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- LANCL1 | c.1076G>C p.G359A | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LCE1F | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAMLD1 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAP2 | c.316C>A p.L106M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MED1 | c.2509G>C p.D837H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MLKL | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPHOSPH8 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MTAP | c.364C>G p.Q122E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.048); called by muse, mutect2
- MTMR4 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.24975G>C p.L8325F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- MYEOV | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 164/206 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- NBPF11 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.13); called by muse, mutect2
- NEDD4 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.156); called by muse, mutect2
- NEU1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- OBSCN | c.17971A>T p.I5991F | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- PCCA | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PCDHGB6 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCSK6 | c.2647G>T p.E883* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2, varscan2
- PDE10A | c.2112G>T p.K704N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PEAK1 | c.3919G>A p.D1307N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIK3CB | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); called by muse, mutect2
- PKP4 | c.3250T>G p.Y1084D | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PLAU | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PLD5 | c.1338T>A p.D446E (on ENST00000442594; = p.D384E on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.912); called by muse, mutect2
- PPFIBP1 | c.1466G>C p.R489T (on ENST00000318304 / NM_177444.3; = p.R472T on NM_003622.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAG1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMG2 | c.734G>C p.W245S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTH2R | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RC3H1 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- REM2 | c.345C>G p.F115L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.318); called by muse, mutect2
- REV3L | c.4127C>T p.S1376F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); called by muse, mutect2
- RGS6 | c.854G>C p.S285T | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- RNF145 | c.442C>A p.L148M (on ENST00000424310 / NM_001199383.2; = p.L176M on NM_144726.2) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEC23A | c.2209G>T p.E737* | Nonsense Mutation (SNP) | VAF 17/167 reads (10%) | called by muse, mutect2
- SENP1 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SIM1 | c.1168-1G>C p.X390_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- SLC17A2 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC38A1 | c.980T>C p.I327T | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.155); called by muse, mutect2
- SLC38A7 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC3A1 | c.1952A>T p.N651I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- SORCS1 | c.1615G>C p.G539R | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA31D1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.451); called by muse, mutect2
- SPDYC | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- STAT4 | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SYCE1 | c.334C>G p.L112V (on ENST00000343131 / NM_001143764.3; = p.L76V on NM_130784.3) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2
- TACC2 | c.863G>C p.R288T | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); called by muse, mutect2
- THOC2 | c.1245G>C p.K415N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRPC4 | c.2620C>T p.Q874* (on ENST00000379705 / NM_016179.4; = p.Q879* on NM_003306.3) | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.86561G>C p.R28854T (on ENST00000591111; = p.R21430T on NM_003319.4) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- TTN | c.32048T>A p.F10683Y (on ENST00000591111; = p.F9756Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TTPA | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- VPS54 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VXN | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- YTHDF1 | c.950A>T p.Y317F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZMYND12 | c.636G>C p.R212S | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.056); called by muse, mutect2
- ZNF184 | c.1059G>C p.Q353H | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ZNF559 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADAM12 | c.2355G>A p.P785= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs375026997; called by muse, mutect2, varscan2
- AMOTL2 | c.588G>A p.L196= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs200498719; called by muse, mutect2
- ARHGEF17 | c.873G>A p.G291= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- ARL4C | c.150G>A p.E50= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- ARPP21 | c.1230C>T p.S410= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs781699865; called by muse, mutect2, varscan2
- ASPHD2 | c.546C>T p.D182= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs747823171; called by muse, mutect2, varscan2
- BRMS1 | c.249G>C p.L83= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs769414940, COSV100240381; called by mutect2, varscan2
- BRWD1 | c.3117C>T p.F1039= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- C1QTNF2 | c.714G>A p.G238= (on ENST00000393975; = p.G193= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- CADM3 | c.489C>T p.L163= (on ENST00000368125 / NM_001127173.3; = p.L197= on NM_021189.5) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs554827373; called by muse, mutect2, varscan2
- CDH23 | c.4029C>T p.L1343= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- CNGB3 | c.2262T>G p.P754= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- CREBRF | c.39C>T p.F13= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs748475579; called by muse, mutect2, varscan2
- DST | c.7050G>C p.V2350= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV55022040; called by muse, mutect2
- FOXF2 | c.474C>T p.F158= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV52525667; called by muse, mutect2, varscan2
- GALNT10 | c.291C>T p.P97= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs1476877738, COSV99769600; called by muse, mutect2, varscan2
- IL16 | c.507C>T p.L169= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100267410; called by muse, mutect2
- IL36B | c.72G>C p.L24= | Silent (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2, varscan2
- KCNC4 | c.846C>G p.T282= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
- KCTD16 | c.471C>G p.L157= | Silent (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- KIAA1755 | c.2025C>T p.L675= | Silent (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- LAMB1 | c.1092C>T p.D364= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- MAGEA6 | c.612C>T p.I204= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as rs1556826650; called by muse, mutect2, varscan2
- MCOLN3 | c.255G>A p.Q85= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs374738596; called by muse, mutect2, varscan2
- METTL7A | c.324C>T p.I108= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100153752; called by muse, mutect2, varscan2
- MGAT4B | c.942G>C p.L314= | Silent (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- MMP11 | c.267G>A p.L89= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs1310167786, COSV53157045; called by muse, mutect2, varscan2
- MOCOS | c.591C>T p.L197= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- MOSPD2 | c.549G>C p.V183= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- MRPS17 | c.258C>T p.F86= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV99567773; called by muse, mutect2, varscan2
- MRPS22 | c.12C>T p.L4= | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- MUC2 | c.951G>C p.V317= | Silent (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2
- MYH1 | c.765C>T p.F255= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as rs565550881, COSV56843987; called by muse, mutect2, varscan2
- NGEF | c.717C>T p.I239= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV50936244; called by muse, mutect2, varscan2
- ODF2L | c.1617G>A p.Q539= (on ENST00000317336; = p.Q523= on NM_020729.3) | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- OR56A3 | c.687G>C p.V229= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV61569774; called by muse, mutect2, varscan2
- PKIG | c.33C>T p.F11= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs762724888; called by muse, mutect2, varscan2
- PPARGC1B | c.288C>T p.L96= | Silent (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- PRKAA1 | c.402C>T p.I134= | Silent (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- PRPSAP1 | c.519C>T p.F173= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- RBM14 | c.117C>T p.F39= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs754533623, COSV59560068; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>C p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs778061023, COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- RNF148 | c.540G>C p.G180= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs770706381; called by muse, mutect2, varscan2
- RNF220 | c.1296G>A p.R432= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ST8SIA3 | c.108G>A p.E36= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs1183324417, COSV100129366; called by muse, mutect2, varscan2
- SYNE1 | c.462C>T p.S154= (on ENST00000367255 / NM_182961.4; = p.S161= on NM_033071.3) | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs761939786; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TEX2 | c.2559C>T p.L853= (on ENST00000583097 / NM_001288733.2; = p.L860= on NM_018469.5) | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as rs1483243727, COSV51985455; called by muse, mutect2
- TNS3 | c.1869C>G p.V623= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100235213; called by muse, mutect2
- TULP2 | c.1431C>A p.I477= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV55479399; called by muse, mutect2, varscan2
- WDR31 | c.432C>T p.G144= (on ENST00000374193 / NM_001006615.3; = p.G143= on NM_145241.5) | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- XPO5 | c.1134C>T p.L378= | Silent (SNP) | VAF 16/73 reads (22%) | called by muse, mutect2, varscan2
- ZNF792 | c.130C>T p.L44= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- ADD2 | c.1742-268C>A | Intron (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100036210; called by muse, mutect2, varscan2
- CSF3R | c.*195G>C | 3'UTR (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- IMP4 | c.-2A>G | 5'UTR (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640590 ins T | 3'Flank (INS) | VAF 5/56 reads (9%) | called by mutect2, pindel
- MSR1 | c.1033+2511A>C | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- PRKCD | c.-1C>T | 5'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.14536C>T | RNA (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- VAPA | c.418-5346G>A | Intron (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
